Surgical pathology report (de-identified scan), TCGA case TCGA-ZH-A8Y1, project TCGA-CHOL (Cholangiocarcinoma), tissue source site University of North Carolina, specimen TCGA-ZH-A8Y1-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3

Cholangiocarcinoma 8/60/3
Site: Intrahepatic bile duct
0.22.1

NO 4/13/14

Diagnosis:

A: Liver lesion, "Level 5", excision

- Adenocarcinoma, moderately differentiated, of intrahepatic bile ducts (primary hepatic cholangiocarcinoma), 4.5 mm
- Carcinoma is less than 1 mm from inked parenchymal margin
- Dysplasia of the intraductal biliary epithelium (see comment)

B: Liver, Segment 8, excision

- Adenocarcinoma, moderately differentiated, of intrahepatic bile ducts (primary hepatic cholangiocarcinoma), at least two separate foci by gross examination, 0.4 and 0.8 cm
- Inked parenchymal margin (definitive margin) positive for carcinoma (B2)
- Dysplasia of the intraductal biliary epithelium and intraductal biliary papillary carcinoma in situ, multifocal

C: Liver, Segments 2-5, partial hepatectomy

- Adenocarcinoma, moderately differentiated, of intrahepatic bile ducts (primary hepatic cholangiocarcinoma), at least 11.2 cm by gross measurement
- Dysplasia of the intraductal biliary epithelium and intraductal biliary papillary carcinoma in situ, multifocal
- Inked parenchymal margin is extensively positive for invasive carcinoma (C1)
- Bile duct margin is positive for dysplasia (C9)
- Invasive carcinoma extends into perihepatic fibroadipose tissue
- Lymphovascular space invasion is identified
- AJCC stage: pT3 pN1 (see comment)

D: Lymph nodes, perihepatic, excision

- One of eleven lymph nodes positive for metastatic adenocarcinoma (1/11)
- Size of metastasis is 0.6 cm
- Extracapsular extension identified

Comment:

The liver displays a spectrum of intraductal biliary neoplasia. In some bile duct profiles the epithelium is dysplastic without papillary structure formation. In other bile duct profiles, intraductal biliary papillomatosis is present as multifocal

[page 2 of 4]
papillary lesions. Intraductal papillary carcinoma is considered to be the in situ lesion for the invasive cholangiocarcinoma, and is related to the pancreatic intraductal mucinous neoplasm. Dysplasia of the bile duct epithelium without papillomatosis most likely is part of the same neoplastic process in this case. The invasive tumor does not have papillary architecture, and is a conventional gland-forming adenocarcinoma. Invasive carcinoma is present as large mass lesions/nodules (mass forming subtype). Extensive peri-ductal invasion (carcinoma spread along intact biliary tree) is not identified. The tumor is staged as a pathologic T3 because of invasion into perihepatic fibroadipose tissue at the round ligament.

Clinical History:

-year-old female with intrahepatic malignant neoplasm consistent with cholangiocarcinoma.

Gross Description:

Received are four formalin-filled containers.

Container A is additionally labeled "Level 5 liver lesion." It holds a 0.8 x 0.7 x 0.4 cm wedge-shaped fragment of gray/tan liver which is partially covered with a smooth capsule. The parenchymal surface is inked black and the specimen is sectioned to reveal a 0.5 x 0.4 x 0.3 cm circumscribed white subcapsular nodule abutting the black inked parenchymal margin. The specimen is serially sectioned and entirely submitted in block A1,

Container B is additionally labeled "Segment 8 liver." The requisition states: stitch marks definitive segment 8 margin. It holds a 3.1 gram, 2.4 x 2.2 x 1.7 cm friable fragment of liver tissue with two sutures present on one surface designating definitive margin. This surface is inked black, and the opposite surface is inked red for identification purposes. The specimen is sectioned perpendicular to the black inked margin and entirely submitted in blocks B1-B5. Sectioning reveals two white circumscribed nodules which are 0.4 and 0.8 cm in greatest dimension. Each nodule abuts the red inked margin opposite the sutured margin. The smaller nodule comes within 0.2 cm of the black inked sutured margin (B3), and the larger nodule comes within 0.3 cm of the black inked sutured margin (B1).

[page 3 of 4]
Block Summary:

B1-B5,

Container C is additionally labeled "Liver, Segments 2-5." It consists of a 545 gram, 18 x 13 x 5 cm partial hepatectomy specimen composed of Segments 2-5. The capsule is brown/gray, focally plaque-like. The parenchymal margin is inked blue. There is a small amount of attached fat along the inferior edge of Segment 5. Along the medial edge of the parenchymal margin there is a 3.4 x 2.9 cm fragment of fibromembranous tissue and cauterized fat. This area is adherent upon the capsule. Sectioning demonstrates a dominate nodule surrounded by multiple butting nodules off its edge and within the remainder of the parenchyma. The dominate nodule is 11.2 x 9.8 x 4.4 cm. The smaller nodule within the parenchyma and subcapsular range from 0.1 to 4 cm in greatest dimension. The closest approach to the parenchymal margin (inked black) is 0.2 cm. The tumor has a solid gritty yellow/tan cut surface with areas of firm, white tissue at the periphery. The surrounding hepatic parenchyma is homogeneous tan/gray with no micronodular pattern identified.

Tumor and normal are given to Tissue Procurement.

Block Summary:

C1 - tumor nodules at closest approach to black inked parenchymal margin
C2-C3 - fibromembranous tissue adherent near surgical margin
C4-C5 - additional section near adherent fatty tissue at round ligament insertion
C6 - edge of tumor and large caliber lumina
C7-C8 - additional sections of tumor
C9-C11 - additional sections, en face, from surgical margin, lumina

Container D is additionally labeled "perihepatic lymph node." It consists of a 3.7 x 2.6 x 1.5 cm aggregate of cauterized yellow/tan fibrofatty tissue which is dissected for lymph node candidates. Lymph node candidates up to 3.1 cm in greatest dimension are identified.

[page 4 of 4]
Block summary:

D1 - four lymph node candidates

D2 - two lymph node candidates

D3 - one bisected lymph node candidate

D4-D5 - one sectioned lymph node candidate

A small amount of fat remains in formalin.

Source: NCI Genomic Data Commons file 714e6003-2043-4b9d-9aef-1f8cd565c53f (TCGA-ZH-A8Y1.B4025F42-46CB-4D4E-ABB4-DBF701615F14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).